Gene-level copy-number profile of tumor specimen C3N-01758-03 from CPTAC case C3N-01758, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.4 years (21,708 days).
Specimen C3N-01758-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b3f8cc39-50d1-4c06-a282-19b1204b4409.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01758-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/8e55c4c2-d04b-4e80-a165-3b3d02a20daf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 8,122; copy number 2: 44,337; copy number 3: 4,407; copy number 4: 1,137; copy number 5: 371.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,128,103, 10 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:42,183,659–42,626,813, 14 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5.
- chr9:64,488,600–64,498,745, 2 genes: GXYLT1P6, AL773524.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 371 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:37,212,178–54,945,099, 363 genes, copy number 5 (broad region; genes not listed).
- chr14:24,036,453–24,132,849, 8 genes, copy number 5: DHRS4L1, CARMIL3, CPNE6, NRL, PCK2, DCAF11, AL136295.3, FITM1.

Autosomal genes at a single copy (total copy number 1): 5,782. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
